Gene-level copy-number profile of tumor specimen TCGA-EB-A44Q-06A from TCGA case TCGA-EB-A44Q, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 51.8 years (18,932 days).
Specimen TCGA-EB-A44Q-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.47dbcaa0-fbad-4b86-8480-d9434b9c9e81.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EB-A44Q-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/27f5fd2b-d3af-4efd-81b4-512847245594

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 4,538; copy number 2: 46,269; copy number 3: 6,762; copy number 4: 1,313; copy number 5: 125; copy number 6: 158; copy number 7: 128; copy number 8: 187; copy number 9: 31; copy number 10: 35; copy number 11: 3; copy number 12: 54; copy number 13: 79; copy number 14: 12; copy number 15: 65; copy number 17: 1; copy number 18: 20; copy number 19: 16; copy number 21: 3; copy number 49: 7; copy number 59: 2; copy number 74: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EB-A44Q-06A-11D-A25P-01): tumor purity 0.64, ploidy 2.16, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:37,980,676–38,226,897, 3 genes: LINC02345, LINC01852, AC087473.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 930 genes in 45 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:69,168,782–70,620,325, 13 genes, copy number 49–74 (within-gene range 2–74): FRMD4B, RBM43P1, AC099328.1, AC099328.2, AC104445.1, MITF, RN7SL418P, SAMMSON, AC139700.1, UQCRHP4, MDFIC2, AC104633.1, AC104633.2.
- chr5:4,451,930–4,866,311, 3 genes, copy number 12 (within-gene range 2–12): AC106799.2, AC106799.1, AC010634.1.
- chr5:4,967,764–5,140,119, 7 genes, copy number 12: AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2.
- chr5:13,637,919–14,699,850, 11 genes, copy number 14: AC016546.1, DNAH5, AC016576.1, TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN.
- chr5:14,728,587–14,734,258, 1 gene, copy number 14: AC010491.2.
- chr5:16,373,361–16,936,288, 8 genes, copy number 15 (within-gene range 2–15): LINC02150, AC020980.1, ZNF622, RETREG1, AC024588.1, AC022113.1, Y_RNA, MYO10.
- chr5:17,604,177–18,049,872, 16 genes, copy number 6: TAF11L11, TAF11L12, H3P19, H3P20, H3P21, TAF11L13, TAF11L14, AC233724.4, AC233724.1, AC233724.5, AC233724.2, H3Y1, AC233724.8, H3P22, LINC02223, RPL36AP21.
- chr5:18,886,622–18,909,543, 3 genes, copy number 6: UBE2V1P12, AC025768.1, AC114981.1.
- chr5:20,158,662–20,347,972, 3 genes, copy number 8: AC093303.1, AC094103.1, CDH18-AS1.
- chr5:22,212,476–22,766,824, 3 genes, copy number 13: AC138854.1, GCNT1P2, AC091938.1.
- chr5:23,262,159–24,749,772, 21 genes, copy number 5–21: AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1, C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1, AC010387.1, Metazoa_SRP, AC010387.2, CDH10, AC091885.2, AC091885.1, AC091893.2, AC091893.1.
- chr5:25,087,450–26,484,711, 15 genes, copy number 5–15: LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2, RNU6-374P, AC022418.1, MSNP1, AC113370.1, RNU4-43P, AC025475.1, AC025475.2.
- chr5:32,522,758–32,791,724, 5 genes, copy number 7 (within-gene range 3–7): AC074134.1, SUB1, LINC02061, AC008766.1, NPR3.
- chr5:33,090,126–33,522,230, 8 genes, copy number 9: AC010343.2, AC010343.1, LINC02160, AC025472.1, AC034231.1, TARS1, TOMM40P3, AC034232.1.
- chr5:33,986,165–34,158,767, 7 genes, copy number 8 (within-gene range 3–8): AMACR, C1QTNF3-AMACR, AC139783.1, C1QTNF3, AC139792.2, AC139792.3, AC139792.1.
- chr5:34,837,549–35,938,779, 18 genes, copy number 7 (within-gene range 3–7): AC026801.2, TTC23L, AC026801.1, RPL21P54, RAD1, BRIX1, DNAJC21, AGXT2, PRLR, AC010368.1, U3, SPEF2, RNU7-130P, AC137810.1, IL7R, AC112204.3, AC112204.1, CAPSL.
- chr5:36,098,407–42,191,523, 99 genes, copy number 8–17 (within-gene range 3–17) (broad region; genes not listed).
- chr5:42,465,400–42,468,868, 2 genes, copy number 6: SERBP1P6, AC093225.1.
- chr11:69,000,765–72,674,591, 130 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).
- chr11:74,988,279–75,815,406, 35 genes, copy number 6: NEU3, AP003175.1, OR2AT2P, NPM1P50, OR2AT4, AP001972.4, SLCO2B1, OR2AT1P, AP001972.3, ZDHHC20P3, TPBGL, ARRB1, AP001972.1, AP001972.5, AP001972.2, MIR326, RPS3, SNORD15A, SNORD15B, KLHL35, GDPD5, AP002815.1, SERPINH1, AP001922.5, MAP6, AP001922.6, AP001922.2, AP001922.4, MOGAT2, RN7SL786P, AP001922.1, DGAT2, AP001922.3, AP003031.1, UVRAG-DT.
- chr11:75,835,215–75,837,645, 2 genes, copy number 6: Y_RNA, Y_RNA.
- chr12:41,409,467–41,473,510, 1 gene, copy number 8 (within-gene range 2–8): AC090531.1.
- chr12:46,358,188–47,420,192, 24 genes, copy number 10 (within-gene range 3–10): SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4, AC079906.1, AMIGO2, PCED1B, IFITM3P6, MIR4698, PCED1B-AS1, AC008083.2, AC008083.3, AC008083.4, PPIAP45, AC008083.1, LINC02416, MIR4494, LINC02156.
- chr12:49,836,043–50,289,231, 25 genes, copy number 6 (within-gene range 3–6): BCDIN3D, AC131157.1, RPL35AP28, FAIM2, LINC02395, LINC02396, AQP2, AC025154.2, AC025154.1, AQP5, AQP6, RACGAP1, ASIC1, SMARCD1, GPD1, COX14, AC074032.1, CERS5, LIMA1, AC008147.2, AC008147.3, AC008147.1, MIR1293, RNU6-1093P, AC008147.4.
- chr12:55,009,746–55,132,750, 5 genes, copy number 9: AC027287.2, NEUROD4, OR9K1P, AC027287.1, OR9K2.
- chr12:57,253,762–61,232,937, 79 genes, copy number 5–18 (within-gene range 4–18) (broad region; genes not listed).
- chr12:62,139,999–62,235,515, 2 genes, copy number 6: AC078789.1, KLF17P1.
- chr12:69,901,918–70,243,379, 1 gene, copy number 6 (within-gene range 3–6): PRANCR.
- chr12:70,180,338–71,032,083, 13 genes, copy number 6: LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1.
- chr12:74,274,952–74,293,096, 2 genes, copy number 6: AC090502.1, VENTXP3.
- chr12:78,052,181–78,359,746, 3 genes, copy number 7: AC073571.1, PRXL2AP1, LINC02424.
- chr12:80,936,414–82,515,817, 16 genes, copy number 19 (within-gene range 2–19): ACSS3, AC078955.1, MIR4699, PPFIA2, PPFIA2-AS1, AC069228.1, AC079363.1, AC091515.1, LINC02426, AC011602.1, CCDC59, METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1.
- chr12:82,686,880–83,172,740, 4 genes, copy number 5 (within-gene range 4–8): TMTC2, RNU6-977P, RPL6P25, AC090680.1.
- chr12:87,944,885–88,602,195, 12 genes, copy number 7: RPS4XP15, C12orf50, C12orf29, CEP290, RNA5SP364, AC091516.1, TMTC3, Y_RNA, KITLG, AC024941.2, RNU1-117P, AC024941.1.
- chr12:111,753,890–113,017,751, 33 genes, copy number 7 (within-gene range 2–7): AC002996.1, ALDH2, MIR6761, MAPKAPK5-AS1, MAPKAPK5, RPS2P41, ADAM1A, ADAM1B, TMEM116, SLC25A3P2, AC004024.1, ERP29, AC073575.2, NAA25, MIR3657, AC073575.1, Y_RNA, TRAFD1, Y_RNA, HECTD4, MIR6861, AC004217.1, RN7SKP71, RPL7AP60, AC004217.2, RPL6, PTPN11, RPH3A, MIR1302-1, OAS1, AC004551.1, OAS3, OAS2.
- chr12:114,408,173–116,536,518, 38 genes, copy number 5–18: TBX5-AS1, RN7SKP216, AC069240.1, OSTF1P1, AC010177.1, Y_RNA, TBX3, AC026765.3, AC026765.4, AC026765.1, AC026765.2, AC009804.2, AC009804.1, AC008125.1, AC078880.1, AC078880.3, AC078880.4, AC078880.5, AC078880.2, AC009803.2, AC009803.1, UBA52P7, RN7SL865P, AC009387.1, LINC02463, AC012157.1, AC012157.3, MED13L, AC012157.2, RNU6-1188P, MIR620, SNRPGP18, AC130895.1, AC079384.2, AC079384.1, MIR4472-2, LINC02457, LINC00173.
- chr12:118,645,315–118,738,511, 2 genes, copy number 5: LINC02460, RPL17P37.
- chr12:119,959,424–127,060,565, 243 genes, copy number 5–13 (broad region; genes not listed).
- chr12:127,142,029–127,146,532, 1 gene, copy number 8: AC079949.1.
- chr12:127,274,265–127,590,930, 11 genes, copy number 8 (within-gene range 3–8): LINC02376, AC073913.1, RNU1-104P, LINC02375, AC073913.2, AC048347.1, AC068787.4, AC068787.1, AC068787.3, AC068787.2, AC068787.5.

Autosomal genes at a single copy (total copy number 1): 4,538. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
